Gene-level copy-number profile of specimen HCM-SANG-0283-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0283-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0283-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1d583ff-9352-4ea4-b78a-01c48b415298.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0283-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/282269ae-0a07-4c44-8b5d-b6819c5b7f7c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 511; copy number 1: 466; copy number 2: 1,604; copy number 3: 16,444; copy number 4: 18,677; copy number 5: 6,098; copy number 6: 11,684; copy number 7: 1,721; copy number 8: 675; copy number 9: 936; copy number 10: 37; copy number 11: 9; copy number 12: 5; copy number 13: 9; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 997 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,549,415–118,185,228, 10 genes, copy number 9–12: VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17.
- chr1:248,548,756–248,645,278, 9 genes, copy number 13: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr7:37,032–31,708,455, 547 genes, copy number 9 (broad region; genes not listed).
- chr7:41,960,949–62,275,678, 325 genes, copy number 9 (broad region; genes not listed).
- chr9:41,310,816–41,648,035, 9 genes, copy number 11: AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5.
- chr9:41,890,314–42,499,134, 14 genes, copy number 10: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:61,190,003–61,642,494, 10 genes, copy number 9–10: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:64,810,865–64,836,341, 2 genes, copy number 12–14: BNIP3P4, AL359955.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 9: BMS1P12, AL512605.1, AL512605.2.
- chr13:18,467,172–20,232,365, 67 genes, copy number 9–10 (broad region; genes not listed).
- chr16:7,878,799–8,112,756, 1 gene, copy number 9: AC093515.1.

Autosomal genes at a single copy (total copy number 1): 466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
